Somatic mutation profile of tumor specimen CDDP-ABIW-TTP1-A (aliquot CDDP-ABIW-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABIW, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40 years.
Specimen CDDP-ABIW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44da3a67-265c-462a-87fa-4517c09be197.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABIW-NB1-A (Blood Derived Normal), aliquot CDDP-ABIW-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6edba73c-c886-4649-9afe-07c4977a15cd

The open-access MAF lists 574 somatic variants for this specimen: 385 protein-altering or splice-affecting, 125 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 326, Silent 125, Nonsense Mutation 30, Intron 23, RNA 13, 5'Flank 10, Splice Site 10, 5'UTR 9, 3'UTR 6, Frame Shift Del 6, Splice Region 5, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.8512C>T p.R2838* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs137853032, CM091951, COSV62103744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 225/287 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; called by muse, mutect2, varscan2
- AK5 | c.905G>T p.R302L (on ENST00000354567 / NM_174858.3; = p.R276L on NM_012093.4) | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100642274; called by muse, mutect2, varscan2
- AKAP13 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775361535, COSV63457448; called by muse, mutect2, varscan2
- AMER3 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV100366356; called by muse, mutect2, varscan2
- ANKFN1 | c.3723C>G p.Y1241* (on ENST00000653862; = p.Y1094* on NM_001365758.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/388 reads (12%) | catalogued as rs1414489871; called by muse, mutect2, varscan2
- ANKRD30B | c.2798G>T p.W933L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV100271413, COSV100271643; called by muse, varscan2
- APCDD1 | c.1087G>T p.V363L | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV62373618; called by muse, mutect2, varscan2
- ASPM | c.8659G>A p.V2887M | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs370820270; called by muse, mutect2
- ATG2A | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs1006407090; called by muse, mutect2
- ATIC | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200997625; called by muse, mutect2, varscan2
- BRINP3 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs147799875, COSV66532324, COSV66543305; called by muse, mutect2, varscan2
- CDH4 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs755112377; called by muse, mutect2, varscan2
- CEBPA | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57195750, COSV57200441; called by muse, mutect2, varscan2
- CIRBP | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 115/165 reads (70%) | catalogued as COSV100309833; called by muse, mutect2, varscan2
- CLVS1 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV57985536; called by muse, mutect2, varscan2
- CSMD3 | c.9898G>T p.G3300* (on ENST00000297405 / NM_001363185.1; = p.G3131* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 81/301 reads (27%) | catalogued as COSV52335055; called by muse, mutect2, varscan2
- CSMD3 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs143125587; called by muse, mutect2, varscan2
- CST11 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs747708496; called by muse, mutect2, varscan2
- CTDP1 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1331561490; called by muse, mutect2, varscan2
- CTNND2 | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 54/208 reads (26%) | catalogued as COSV58928489; called by muse, mutect2, varscan2
- CUBN | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 146/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752992672, COSV64725404; called by muse, mutect2, varscan2
- CYRIA | c.601A>G p.S201G | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV62864710; called by muse, mutect2, varscan2
- DCUN1D2 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.548); catalogued as COSV60261862; called by muse, mutect2, varscan2
- DLC1 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.024); catalogued as COSV52327506; called by muse, mutect2, varscan2
- EFL1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772344093; called by muse, mutect2, varscan2
- ELMOD1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56196951; called by muse, mutect2, varscan2
- ERICH3 | c.3673G>T p.G1225* | Nonsense Mutation (SNP) | VAF 57/199 reads (29%) | catalogued as COSV58601229; called by muse, mutect2, varscan2
- EVX2 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 109/484 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57962662; called by muse, mutect2, varscan2
- EXD1 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100153896; called by muse, mutect2, varscan2
- FAM135B | c.3619C>G p.L1207V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52749849; called by muse, mutect2, varscan2
- FAM216A | c.703G>C p.V235L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV62194715; called by muse, mutect2, varscan2
- GAB4 | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV68755452; called by muse, mutect2, varscan2
- GALNT10 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs757619293, COSV51722208; called by muse, mutect2, varscan2
- GALNTL6 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV72492906; called by muse, mutect2, varscan2
- GNAS | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 59/425 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs771378819; called by muse, mutect2, varscan2
- GOLGA8M | c.1897T>A p.*633Kext*? | Nonstop Mutation (SNP) | VAF 83/400 reads (21%) | catalogued as rs1356891452; called by muse, mutect2, varscan2
- GPR158 | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV66268695; called by muse, mutect2
- GPR27 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV55205102; called by mutect2, varscan2
- GRM1 | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs866444209; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2408G>A p.R803Q (on ENST00000265755 / NM_016328.3; = p.R788Q on NM_005685.4) | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs587668148, COSV56085867; called by muse, mutect2, varscan2
- GXYLT2 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774450522, COSV67473463, COSV67475521; called by muse, mutect2, varscan2
- H3C10 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.015); catalogued as rs756702685; called by muse, mutect2, varscan2
- IGKV1-27 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 51/332 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs536763828; called by muse, mutect2, varscan2
- IMPG2 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51985532; called by muse, mutect2, varscan2
- INF2 | c.701G>C p.R234P | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53030798; called by muse, mutect2, varscan2
- INVS | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52445793; called by muse, mutect2, varscan2
- IRX4 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261260838, COSV99180801; called by muse, mutect2, varscan2
- ITGA9 | c.1391C>G p.T464R | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV53236108; called by muse, mutect2, varscan2
- KCNJ16 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 612/821 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.277); catalogued as COSV52257045; called by muse, mutect2, varscan2
- KCNMB1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs565730657; called by muse, mutect2, varscan2
- KCP | c.2247C>A p.F749L (on ENST00000620378; = p.F809L on NM_001366122.1) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); catalogued as COSV99925889; called by muse, mutect2, varscan2
- KIF5C | c.2779C>A p.R927S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV68479789; called by muse, mutect2, varscan2
- KLC3 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV99059928; called by muse, mutect2, varscan2
- KMT2C | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1390701611; called by muse, mutect2, varscan2
- KRT6C | c.105C>G p.S35R | Missense Mutation (SNP) | VAF 126/760 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1325963105; called by muse, mutect2, varscan2
- KRTAP19-3 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as rs753696243; called by muse, mutect2, varscan2
- KRTAP3-1 | c.142T>G p.C48G | Missense Mutation (SNP) | VAF 147/536 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs746105523; called by muse, mutect2, varscan2
- KYNU | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51585371; called by muse, mutect2, varscan2
- LAMB4 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 320/459 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1221069821; called by muse, mutect2, varscan2
- LAMP5 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1184540341; called by muse, mutect2, varscan2
- LDB3 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs143311349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LONP2 | c.1729G>C p.V577L | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV53521046; called by muse, mutect2, varscan2
- LRP1B | c.6122G>A p.W2041* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV67236792, COSV67238175; called by muse, mutect2, varscan2
- MAGEA3 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 95/132 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs782179243; called by muse, mutect2, varscan2
- MED12 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as COSV61334354; called by muse, varscan2
- MEIOC | c.2249C>A p.P750Q | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs773181104; called by muse, varscan2
- MROH2B | c.2959A>T p.K987* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as COSV101270418; called by muse, mutect2, varscan2
- MUC16 | c.25646G>T p.W8549L | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV101200599; called by muse, mutect2, varscan2
- NETO1 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100197982; called by muse, mutect2, varscan2
- NIP7 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201518205; called by muse, mutect2, varscan2
- NLRP10 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.808); catalogued as COSV60778612; called by muse, mutect2, varscan2
- NOMO1 | c.3392C>G p.S1131C | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99814381; called by mutect2, varscan2
- NOSIP | c.725+1G>C p.X242_splice | Splice Site (SNP) | VAF 59/85 reads (69%) | catalogued as rs751378014, COSV59199126; called by muse, mutect2, varscan2
- NOTCH4 | c.5687A>G p.H1896R | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66684643; called by muse, mutect2, varscan2
- NPAP1 | c.1690C>A p.H564N | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61505755; called by muse, mutect2, varscan2
- NPAP1 | c.2441C>T p.S814L | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs141727384, COSV61507736; called by muse, mutect2, varscan2
- NYAP1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.275); catalogued as rs1291253460, COSV55721719; called by muse, mutect2, varscan2
- OR11A1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.74); catalogued as COSV65821417; called by muse, mutect2, varscan2
- OR2F2 | c.753C>A p.C251* | Nonsense Mutation (SNP) | VAF 84/130 reads (65%) | catalogued as rs764010721; called by muse, mutect2, varscan2
- OR51V1 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.515); catalogued as rs993776075; called by muse, mutect2, varscan2
- OSBPL6 | c.2689T>A p.F897I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51918858; called by muse, mutect2, varscan2
- PAFAH2 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 108/173 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs144938380; called by muse, mutect2, varscan2
- PCDHA4 | c.1734C>A p.S578R | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); catalogued as COSV100793351; called by muse, mutect2, varscan2
- PCDHB8 | c.1906G>T p.A636S | Missense Mutation (SNP) | VAF 128/453 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV50753534; called by muse, mutect2, varscan2
- PCDHGA7 | c.2233G>C p.G745R | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as rs763210124; called by muse, mutect2, varscan2
- PIEZO2 | c.4705del p.E1569Kfs*81 | Frame Shift Del (DEL) | VAF 22/160 reads (14%) | catalogued as COSV57441028; called by pindel, varscan2
- PIK3R5 | c.1799G>A p.W600* | Nonsense Mutation (SNP) | VAF 63/194 reads (32%) | catalogued as COSV99353637; called by muse, mutect2, varscan2
- PLEKHM2 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); catalogued as rs370277036; ClinVar: uncertain significance; called by muse, mutect2
- PLPPR5 | c.514A>G p.S172G | Missense Mutation (SNP) | VAF 109/491 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs1214746632; called by muse, mutect2, varscan2
- POMT2 | c.688A>T p.S230C | Missense Mutation (SNP) | VAF 101/315 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs748862291; called by muse, mutect2, varscan2
- PRDM9 | c.1376G>T p.R459M | Missense Mutation (SNP) | VAF 95/490 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.496); catalogued as COSV99691117; called by muse, varscan2
- PRDM9 | c.1377G>T p.R459S | Missense Mutation (SNP) | VAF 98/495 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.083); catalogued as rs112001060, COSV57006728, COSV57010936; called by muse, varscan2
- PXDN | c.3114C>G p.I1038M | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV53234858; called by muse, mutect2, varscan2
- RBM12B | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs372272143; called by muse, mutect2, varscan2
- RELN | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 85/678 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100635162; called by muse, mutect2, varscan2
- RTL1 | c.3006G>T p.R1002S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as COSV66017397; called by muse, mutect2, varscan2
- SATB1 | c.1787A>G p.Q596R | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58670288; called by muse, varscan2
- SCN5A | c.1982G>C p.R661P | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV61129762; called by muse, mutect2, varscan2
- SERPINI2 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.76); catalogued as COSV52985118; called by muse, mutect2, varscan2
- SEZ6L | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173915006, COSV50664889, COSV50670140; called by muse, mutect2, varscan2
- SHROOM3 | c.4382A>G p.Q1461R | Missense Mutation (SNP) | VAF 171/312 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs971483667; called by muse, mutect2, varscan2
- SIRPD | c.481C>A p.H161N | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV67546831; called by muse, mutect2, varscan2
- SLC20A2 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV60603737; called by muse, varscan2
- SLC6A13 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs761840670, COSV58256488; called by muse, mutect2, varscan2
- SLIT1 | c.4276C>A p.Q1426K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771811049; called by muse, varscan2
- SLITRK2 | c.1228A>G p.R410G | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556944443; called by muse, mutect2, varscan2
- STAB2 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs1239987277, COSV66347436; called by muse, mutect2, varscan2
- TFEC | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs766917414; called by muse, mutect2, varscan2
- TIPRL | c.596C>G p.T199R | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751488353; called by muse, mutect2, varscan2
- TLE4 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs771858534; called by muse, mutect2, varscan2
- TLL2 | c.2510A>G p.Y837C | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1298136855; called by muse, mutect2, varscan2
- TMEM229A | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs777941158; called by muse, mutect2, varscan2
- TRIM21 | c.1214G>A p.C405Y | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.187); catalogued as rs759072456; called by muse, mutect2, varscan2
- TTN | c.100858C>A p.P33620T (on ENST00000591111; = p.P26196T on NM_003319.4) | Missense Mutation (SNP) | VAF 47/167 reads (28%) | PolyPhen benign (0.037); catalogued as rs786205336, COSV60069342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.911A>T p.K304M | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV101262805, COSV67138962; called by muse, varscan2
- TUBA3C | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 66/303 reads (22%) | catalogued as COSV67139583; called by muse, varscan2
- TYW1B | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101444352; called by muse, varscan2
- UGT2A1 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99683843; called by muse, mutect2, varscan2
- USP25 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99583213; called by muse, mutect2, varscan2
- WDR72 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 81/237 reads (34%) | catalogued as COSV64745523; called by muse, mutect2, varscan2
- XIRP2 | c.2956G>T p.D986Y (on ENST00000628543; = p.D1161Y on NM_152381.6) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54684673; called by muse, mutect2, varscan2
- ZBTB20 | c.1795G>A p.V599I (on ENST00000474710 / NM_001164342.2; = p.V526I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.984); catalogued as rs1331926530; called by muse, mutect2, varscan2
- ZFHX4 | c.2304del p.C769Vfs*18 | Frame Shift Del (DEL) | VAF 66/275 reads (24%) | catalogued as COSV104378927; called by mutect2, pindel, varscan2
- ZFPM2 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs1389590330, COSV68289862, COSV68292374; called by muse, mutect2
- ZNF423 | c.2242G>A p.A748T (on ENST00000563137 / NM_001379286.1; = p.A740T on NM_015069.4) | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52206981; called by muse, mutect2, varscan2
- ZNF528 | c.1528T>C p.C510R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375985527; called by muse, mutect2, varscan2
- ABCA8 | c.4559C>A p.P1520H | Missense Mutation (SNP) | VAF 89/409 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCC9 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACAP1 | c.2070C>T p.T690= | Splice Region (SNP) | VAF 53/75 reads (71%) | called by muse, mutect2, varscan2
- ACTR1B | c.1025T>A p.I342N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ADAM23 | c.931A>T p.T311S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADAMTS13 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 85/167 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ADGRB3 | c.274C>G p.H92D | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ADH5 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- AGER | c.401C>A p.T134K | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AGMO | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- AKR1C4 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPK1 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ALPK1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMOTL2 | c.2109A>T p.R703S (on ENST00000422605; = p.R704S on NM_016201.4) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- APOB | c.12151G>T p.E4051* | Nonsense Mutation (SNP) | VAF 110/398 reads (28%) | called by muse, varscan2
- ARHGEF10 | c.1187T>A p.F396Y (on ENST00000398564; = p.F371Y on NM_014629.4) | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARHGEF7 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ATP6V1H | c.1349A>G p.Y450C | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B4 | c.3260T>A p.F1087Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- BCAT1 | c.1158_1159insA p.*387Mfs*5 | Frame Shift Ins (INS) | VAF 39/204 reads (19%) | called by mutect2, pindel, varscan2
- BCLAF1 | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRINP3 | c.588C>A p.H196Q | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C16orf89 | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- C3orf38 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CCDC102B | c.170T>A p.F57Y | Missense Mutation (SNP) | VAF 116/419 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CCDC112 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCHCR1 | c.362G>T p.R121M | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CCT3 | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, varscan2
- CCT8 | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD47 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CEACAM19 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CEP112 | c.2233A>G p.K745E | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CEP126 | c.3004A>T p.T1002S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CHKB | c.1012T>G p.L338V | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CHST9 | c.202+2T>A p.X68_splice | Splice Site (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- CLVS2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- COL21A1 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPXM2 | c.1597C>G p.P533A | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRACDL | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF1 | c.1497C>A p.H499Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CSMD3 | c.5510-1G>T p.X1837_splice (on ENST00000297405 / NM_001363185.1; = p.X1733_splice on NM_052900.3) | Splice Site (SNP) | VAF 80/233 reads (34%) | called by muse, mutect2, varscan2
- CYP11A1 | c.1036C>A p.L346M | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- DCAF12L1 | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 90/114 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DDIAS | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DEFA5 | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DHTKD1 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH2 | c.5873C>G p.T1958R | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC3 | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- DNAJC7 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DOCK7 | c.3196A>C p.M1066L (on ENST00000635253 / NM_001367561.1; = p.M1035L on NM_033407.3) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPPA4 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP11 | c.159T>A p.H53Q | Missense Mutation (SNP) | VAF 72/493 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DYNLT3 | c.169A>T p.K57* | Nonsense Mutation (SNP) | VAF 26/40 reads (65%) | called by muse, mutect2, varscan2
- ECHDC3 | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, varscan2
- EIF3E | c.720A>T p.P240= | Splice Region (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- EIF4G3 | c.1496-5_1497del p.X499_splice | Splice Site (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- EP400 | c.6925G>A p.V2309M | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAM161A | c.1772A>C p.Q591P | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM189B | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 150/367 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM3A | c.362_366del p.R121Lfs*2 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel
- FAM53A | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT1 | c.4612G>C p.D1538H | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT2 | c.12831C>A p.Y4277* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- FAT2 | c.7986A>T p.K2662N | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FBN2 | c.6512-1G>T p.X2171_splice | Splice Site (SNP) | VAF 72/259 reads (28%) | called by muse, mutect2, varscan2
- FEZF1 | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FGF13 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 84/107 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- FGF18 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FRAS1 | c.10760C>T p.T3587I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMD1 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 77/109 reads (71%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FSIP2 | c.15257C>A p.P5086H | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FYB1 | c.1001A>T p.K334M | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- G6PC2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GABRA5 | c.254del p.G85Afs*12 | Frame Shift Del (DEL) | VAF 78/403 reads (19%) | called by mutect2, pindel, varscan2
- GALNT17 | c.1463C>G p.T488R | Missense Mutation (SNP) | VAF 133/282 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GAPVD1 | c.3692T>C p.L1231P (on ENST00000394104; = p.L1240P on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GARNL3 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GCN1 | c.6899G>T p.R2300M | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- GLT1D1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GPATCH2L | c.605G>T p.R202M | Missense Mutation (SNP) | VAF 72/109 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GPM6A | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GREB1 | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GRM8 | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HAGHL | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- HERC2 | c.13058_13060dup p.L4353dup | In Frame Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- HIVEP2 | c.3519A>T p.Q1173H | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGCLL1 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- HOPX | c.173G>T p.W58L (on ENST00000317745; = p.W76L on NM_032495.6) | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HTT | c.955A>T p.R319W | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGFN1 | c.2125G>T p.V709L (on ENST00000295591 / NM_001367841.1; = p.V3166L on NM_001164586.2) | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- IGHV3-20 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 114/340 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- IGSF5 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- IKZF1 | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- INSR | c.2369_2407del p.T790_V802del | In Frame Del (DEL) | VAF 140/389 reads (36%) | called by mutect2, pindel
- JMJD1C | c.5192G>T p.C1731F | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNH5 | c.1119C>G p.Y373* | Nonsense Mutation (SNP) | VAF 123/188 reads (65%) | called by muse, mutect2, varscan2
- KCNH8 | c.3149C>G p.S1050* | Nonsense Mutation (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1842del p.E615Rfs*5 (on ENST00000359125 / NM_172107.4; = p.E587Rfs*5 on NM_004518.6) | Frame Shift Del (DEL) | VAF 90/279 reads (32%) | called by mutect2, pindel, varscan2
- KCTD12 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- KIAA1671 | c.2998C>G p.Q1000E | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KIF6 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- KLF6 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 110/531 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- KRTAP26-1 | c.608G>C p.C203S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LAMA3 | c.8432C>T p.T2811I (on ENST00000313654 / NM_198129.4; = p.T1202I on NM_000227.6) | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LAMP5 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCK | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- LIMS2 | c.469G>T p.D157Y (on ENST00000355119 / NM_001161403.3; = p.D181Y on NM_017980.4) | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMOD3 | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2
- LRP10 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- LRP1B | c.2094C>A p.N698K | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.1660G>A p.D554N (on ENST00000651989 / NM_001370785.2; = p.D521N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LZTS2 | c.142_144del p.H48del | In Frame Del (DEL) | VAF 8/43 reads (19%) | called by pindel, varscan2
- MAN2A1 | c.392T>A p.M131K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, varscan2
- MAX | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBIP | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 130/222 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MGAT2 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MICB | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, varscan2
- MRC1 | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MRPL39 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTARC1 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTHFD1 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC19 | c.154A>T p.R52* | Nonsense Mutation (SNP) | VAF 53/180 reads (29%) | called by muse, mutect2, varscan2
- MUC5B | c.6847A>T p.T2283S | Missense Mutation (SNP) | VAF 126/565 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MXD1 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- MYH1 | c.1103A>T p.K368M | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NALCN | c.4149C>A p.F1383L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- NAV3 | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- NID1 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NKD1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NLRP13 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NOTCH2 | c.7036G>T p.A2346S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NPC1L1 | c.2180G>T p.R727M | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- NR1H2 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- NRXN2 | c.3185T>G p.F1062C | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSL1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NUDCD3 | c.1081_*7del | Nonstop Mutation (DEL) | VAF 35/107 reads (33%) | called by mutect2, pindel, varscan2
- NUDT6 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NYAP1 | c.2103C>A p.S701R | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- OBSCN | c.4862-2A>G p.X1621_splice | Splice Site (SNP) | VAF 97/306 reads (32%) | called by muse, mutect2, varscan2
- OPRD1 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR1S2 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 88/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2AG1 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OR51D1 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- OR52N2 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6C75 | c.600A>C p.L200F | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR9Q2 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOA | c.178A>C p.S60R | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OTOGL | c.1418A>G p.N473S (on ENST00000547103; = p.N464S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OVCH1 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- P2RY10 | c.718A>T p.K240* | Nonsense Mutation (SNP) | VAF 95/127 reads (75%) | called by muse, mutect2, varscan2
- PARP6 | c.474C>A p.H158Q | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PAX3 | c.586+7G>T | Splice Region (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- PCDH15 | c.1073A>T p.H358L | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PCDH15 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH19 | c.1532A>C p.N511T | Missense Mutation (SNP) | VAF 208/254 reads (82%) | SIFT tolerated (0.8); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCDHGA4 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PELI3 | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PHGDH | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 125/525 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- PHKA1 | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 158/213 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PHKB | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- PLAA | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PLEKHM1 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 326/834 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PNPLA4 | c.633G>T p.L211F | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POTEC | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POU2AF1 | c.182C>G p.T61S | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPARGC1A | c.1442C>G p.T481S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.01); called by muse, mutect2
- PPP1R3A | c.2003A>T p.N668I | Missense Mutation (SNP) | VAF 92/702 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP3R1 | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPT2 | c.765+1G>T p.X255_splice | Splice Site (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF8 | c.980G>T p.R327M | Missense Mutation (SNP) | VAF 246/1011 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PRDM9 | c.1335C>A p.H445Q | Missense Mutation (SNP) | VAF 104/499 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, varscan2
- PRTG | c.1852+2T>C p.X618_splice | Splice Site (SNP) | VAF 41/122 reads (34%) | called by muse, varscan2
- PRUNE2 | c.7507C>G p.P2503A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRUNE2 | c.1304G>C p.S435T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PSMD7 | c.478A>G p.S160G | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PSPC1 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PTCRA | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- QSER1 | c.1038A>T p.L346F (on ENST00000399302; = p.L475F on NM_001076786.3) | Missense Mutation (SNP) | VAF 120/189 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- RAB33A | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RABGEF1 | c.980A>G p.D327G (on ENST00000439720 / NM_001287061.2; = p.D314G on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 169/434 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM5 | c.1613A>T p.Q538L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- RP1 | c.4189A>T p.S1397C | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RP1 | c.4190G>T p.S1397I | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RPAP3 | c.1131A>T p.L377F | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPS6KA1 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- SACS | c.5839C>T p.P1947S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SACS | c.5838G>C p.W1946C | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEMA3D | c.426C>G p.H142Q | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SENP1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SETD1A | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SFRP2 | c.514T>G p.C172G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SFXN2 | c.736A>T p.I246F | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SKOR2 | c.2381C>A p.S794* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- SLC24A4 | c.1684G>T p.V562L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- SLC26A5 | c.2224C>A p.P742T | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SLC2A10 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC35F1 | c.530T>A p.L177Q | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35F5 | c.984A>C p.V328= | Splice Region (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- SLC6A1 | c.1783A>C p.K595Q | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC7A13 | c.243C>A p.Y81* | Nonsense Mutation (SNP) | VAF 41/151 reads (27%) | called by muse, mutect2, varscan2
- SLC9A3 | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.1420-1G>A p.X474_splice | Splice Site (SNP) | VAF 259/371 reads (70%) | called by muse, mutect2, varscan2
- SNRPC | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- SPPL2C | c.362T>A p.V121E | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SRRM3 | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- STEAP4 | c.1180T>C p.C394R | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- STK11 | c.259del p.R87Gfs*9 | Frame Shift Del (DEL) | VAF 90/160 reads (56%) | called by mutect2, pindel, varscan2
- STK35 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- STON2 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.5889T>A p.C1963* | Nonsense Mutation (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- SYCE1 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SYCP2 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SYDE2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF3 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D10B | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TBC1D15 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | called by muse, varscan2
- TBC1D15 | c.1131G>T p.K377N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- TBC1D32 | c.3371A>T p.Y1124F | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- TET3 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TGFBR2 | c.95-30_111del p.X32_splice | Splice Site (DEL) | VAF 24/254 reads (9%) | called by mutect2, pindel
- TIAM1 | c.4063G>T p.V1355L | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TMEM132D | c.3146C>A p.T1049N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TMEM241 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM67 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- TMPRSS7 | c.1766G>C p.S589T (on ENST00000452346; = p.S463T on NM_001042575.2) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TMUB2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 25/239 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNFSF13B | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TP73 | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TSEN2 | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 90/431 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TSHR | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTC6 | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TTC6 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TTN | c.99835A>T p.T33279S (on ENST00000591111; = p.T25855S on NM_003319.4) | Missense Mutation (SNP) | VAF 61/216 reads (28%) | PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TTN | c.77618T>C p.V25873A (on ENST00000591111; = p.V18449A on NM_003319.4) | Missense Mutation (SNP) | VAF 65/320 reads (20%) | PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TTN | c.71212G>C p.V23738L (on ENST00000591111; = p.V16314L on NM_003319.4) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TTN | c.65806G>T p.D21936Y (on ENST00000591111; = p.D14512Y on NM_003319.4) | Missense Mutation (SNP) | VAF 16/145 reads (11%) | PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- TTN | c.35863G>T p.E11955* (on ENST00000591111; = p.E4531* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- TTN | c.29A>C p.Q10P | Missense Mutation (SNP) | VAF 44/332 reads (13%) | PolyPhen benign (0.363); called by muse, mutect2, varscan2
- TUBGCP4 | c.1451G>T p.S484I (on ENST00000260383 / NM_001286414.3; = p.S483I on NM_014444.5) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TUBGCP5 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 90/391 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TVP23B | c.93C>T p.I31= | Splice Region (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- TXLNB | c.1467C>A p.D489E | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TXNDC15 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- UBE4B | c.2820G>A p.M940I (on ENST00000343090 / NM_001105562.3; = p.M811I on NM_006048.5) | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USP47 | c.237C>G p.N79K (on ENST00000399455 / NM_001372095.1; = p.N59K on NM_001282659.2 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- UTP25 | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- VPS13C | c.878A>C p.Q293P (on ENST00000644861 / NM_020821.3; = p.Q250P on NM_017684.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- WHAMM | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- WWC3 | c.2837_2841dup p.L948Efs*38 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel
- YIPF1 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- YIPF7 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZCWPW2 | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFYVE9 | c.4147C>T p.P1383S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF280C | c.814G>T p.V272F | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF490 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ZNF598 | c.2200A>T p.T734S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF804A | c.1144C>A p.H382N | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZPR1 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.057); called by muse, varscan2
- ADD2 | c.36G>A p.P12= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV52465079; called by muse, mutect2, varscan2
- ADGRD2 | c.1656C>A p.V552= | Silent (SNP) | VAF 83/124 reads (67%) | called by muse, mutect2, varscan2
- AKAP5 | c.840C>A p.A280= | Silent (SNP) | VAF 77/129 reads (60%) | called by muse, mutect2, varscan2
- ALLC | c.1068G>T p.G356= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- APOB | c.3997C>A p.R1333= | Silent (SNP) | VAF 27/250 reads (11%) | catalogued as CM880006; called by muse, mutect2, varscan2
- ARHGAP24 | c.2136G>A p.E712= (on ENST00000395184 / NM_001025616.3; = p.E619= on NM_031305.3) | Silent (SNP) | VAF 90/400 reads (23%) | catalogued as COSV51989976; called by muse, mutect2, varscan2
- ARHGEF28 | c.411G>T p.V137= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- ARMC8 | c.399C>T p.F133= (on ENST00000469044 / NM_001363941.2; = p.F119= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/190 reads (38%) | catalogued as rs762146793; called by muse, mutect2, varscan2
- ATN1 | c.2211C>A p.P737= | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- ATP1B1 | c.789C>T p.F263= | Silent (SNP) | VAF 79/693 reads (11%) | called by muse, mutect2, varscan2
- ATXN2L | c.1545G>T p.G515= | Silent (SNP) | VAF 83/134 reads (62%) | called by muse, mutect2, varscan2
- C11orf80 | c.1062G>A p.V354= | Silent (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- C4orf50 | c.645A>T p.P215= (on ENST00000324058; = p.P1447= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- CADPS | c.768C>A p.A256= | Silent (SNP) | VAF 70/163 reads (43%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.3922C>T p.L1308= | Silent (SNP) | VAF 166/235 reads (71%) | called by muse, mutect2, varscan2
- CAMTA1 | c.4917T>A p.A1639= | Silent (SNP) | VAF 71/128 reads (55%) | called by muse, mutect2, varscan2
- CCT8L2 | c.1305G>T p.G435= | Silent (SNP) | VAF 59/233 reads (25%) | called by muse, mutect2, varscan2
- CD200R1 | c.783T>A p.I261= (on ENST00000471858 / NM_170780.3; = p.I284= on NM_138806.4) | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- CD244 | c.984C>G p.S328= (on ENST00000368033 / NM_001166663.2; = p.S323= on NM_016382.4) | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- CDC42EP5 | c.30G>C p.A10= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- CEP170 | c.819A>T p.T273= | Silent (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- CFAP73 | c.262T>C p.L88= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- COP1 | c.591G>A p.K197= | Silent (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- CPQ | c.1173G>T p.L391= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- CR1 | c.3612G>T p.L1204= | Silent (SNP) | VAF 73/102 reads (72%) | called by muse, mutect2, varscan2
- CRMP1 | c.891G>A p.K297= | Silent (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- DCAF1 | c.1587G>A p.E529= | Silent (SNP) | VAF 84/352 reads (24%) | called by muse, mutect2, varscan2
- DCHS1 | c.7221C>T p.A2407= | Silent (SNP) | VAF 75/339 reads (22%) | called by muse, mutect2, varscan2
- DNAH3 | c.10053C>T p.D3351= | Silent (SNP) | VAF 38/308 reads (12%) | called by muse, mutect2, varscan2
- DNAH9 | c.13278T>C p.P4426= | Silent (SNP) | VAF 32/140 reads (23%) | called by muse, mutect2, varscan2
- DPYD | c.1590G>T p.L530= | Silent (SNP) | VAF 75/331 reads (23%) | catalogued as COSV100929018; called by muse, mutect2, varscan2
- DPYD | c.1398A>G p.P466= | Silent (SNP) | VAF 45/233 reads (19%) | called by muse, mutect2, varscan2
- DSP | c.807G>C p.L269= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as COSV101131247, COSV65793463; called by muse, mutect2, varscan2
- DUOXA2 | c.105A>T p.A35= | Silent (SNP) | VAF 95/322 reads (30%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.5748C>T p.T1916= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs771940514; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF4G3 | c.1503A>T p.I501= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, varscan2
- ELANE | c.54C>G p.A18= | Silent (SNP) | VAF 137/282 reads (49%) | called by muse, mutect2, varscan2
- ENC1 | c.144C>T p.V48= | Silent (SNP) | VAF 63/239 reads (26%) | called by muse, mutect2, varscan2
- EPHX2 | c.1476G>T p.T492= | Silent (SNP) | VAF 50/207 reads (24%) | called by muse, mutect2, varscan2
- ESS2 | c.507G>C p.V169= | Silent (SNP) | VAF 66/302 reads (22%) | catalogued as COSV52816381; called by muse, mutect2, varscan2
- EVC2 | c.3612A>T p.I1204= | Silent (SNP) | VAF 56/379 reads (15%) | called by muse, mutect2, varscan2
- F2R | c.741C>T p.P247= | Silent (SNP) | VAF 45/225 reads (20%) | catalogued as rs762806598; called by muse, mutect2, varscan2
- FOXD4L1 | c.735C>A p.V245= | Silent (SNP) | VAF 125/434 reads (29%) | catalogued as COSV99380655; called by muse, mutect2, varscan2
- FOXF2 | c.420C>T p.A140= | Silent (SNP) | VAF 62/332 reads (19%) | called by muse, mutect2, varscan2
- FRAS1 | c.6375G>T p.G2125= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV99352161; called by muse, mutect2, varscan2
- GABRB3 | c.957G>T p.L319= | Silent (SNP) | VAF 85/396 reads (21%) | called by muse, mutect2, varscan2
- GABRG1 | c.912G>T p.S304= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs773691921; called by muse, mutect2
- GALNT8 | c.540C>A p.L180= | Silent (SNP) | VAF 60/197 reads (30%) | catalogued as rs1476186629; called by muse, mutect2, varscan2
- GALR3 | c.945T>A p.R315= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- GPCPD1 | c.1434C>T p.D478= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- GPR155 | c.1812C>T p.C604= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as rs1235535193; called by muse, mutect2, varscan2
- GRIN2A | c.3006A>C p.T1002= | Silent (SNP) | VAF 92/310 reads (30%) | called by muse, mutect2, varscan2
- H2AC4 | c.39C>T p.A13= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs141604515; called by muse, mutect2, varscan2
- HBG2 | c.249G>A p.K83= | Silent (SNP) | VAF 162/1476 reads (11%) | catalogued as rs1417836676, COSV100400715, COSV57963324; called by muse, varscan2
- KLRC1 | c.267G>T p.T89= | Silent (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- KRTAP3-2 | c.51C>A p.T17= | Silent (SNP) | VAF 202/384 reads (53%) | catalogued as COSV66957142; called by muse, mutect2, varscan2
- LAYN | c.292T>C p.L98= (on ENST00000375615 / NM_001258390.1; = p.L90= on NM_178834.5) | Silent (SNP) | VAF 59/373 reads (16%) | called by muse, mutect2, varscan2
- LONRF2 | c.615G>C p.R205= | Silent (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- LRIT3 | c.342G>A p.G114= | Silent (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- LRRC8A | c.480G>C p.L160= | Silent (SNP) | VAF 66/268 reads (25%) | called by muse, mutect2, varscan2
- LTBR | c.1173G>A p.E391= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1489075486; called by muse, mutect2, varscan2
- MBD6 | c.717C>G p.P239= | Silent (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- MIXL1 | c.424C>A p.R142= | Silent (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- MMP20 | c.252C>A p.T84= | Silent (SNP) | VAF 89/497 reads (18%) | called by muse, mutect2, varscan2
- MPP4 | c.888T>A p.A296= | Silent (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- MUC12 | c.13221A>T p.T4407= (on ENST00000379442; = p.T4264= on NM_001164462.1) | Silent (SNP) | VAF 95/1006 reads (9%) | called by muse, mutect2, varscan2
- MYH8 | c.912C>A p.L304= | Silent (SNP) | VAF 89/225 reads (40%) | called by muse, mutect2, varscan2
- NDRG1 | c.7C>A p.R3= | Silent (SNP) | VAF 62/229 reads (27%) | catalogued as COSV100106276; called by muse, mutect2, varscan2
- NF1 | c.7758A>G p.S2586= (on ENST00000358273 / NM_001042492.3; = p.S2565= on NM_000267.3) | Silent (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- NFE2L2 | c.396C>T p.D132= | Silent (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- NPY4R | c.171G>C p.L57= | Silent (SNP) | VAF 120/333 reads (36%) | called by muse, mutect2, varscan2
- NTF3 | c.231C>A p.P77= | Silent (SNP) | VAF 76/342 reads (22%) | catalogued as rs746534025; called by muse, mutect2, varscan2
- NUDT6 | c.663A>G p.S221= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- OR10Q1 | c.762G>A p.L254= | Silent (SNP) | VAF 44/154 reads (29%) | called by muse, mutect2, varscan2
- OR2T12 | c.738G>C p.V246= | Silent (SNP) | VAF 115/375 reads (31%) | called by muse, mutect2, varscan2
- OSMR | c.741C>T p.T247= | Silent (SNP) | VAF 70/225 reads (31%) | catalogued as rs138387186, COSV57093155; called by muse, mutect2, varscan2
- P2RX2 | c.18C>G p.P6= | Silent (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- PCNT | c.7270C>A p.R2424= | Silent (SNP) | VAF 77/367 reads (21%) | called by muse, mutect2, varscan2
- PDIA5 | c.1422C>T p.P474= | Silent (SNP) | VAF 94/142 reads (66%) | called by muse, mutect2, varscan2
- PIEZO2 | c.4668G>T p.T1556= | Silent (SNP) | VAF 24/147 reads (16%) | called by muse, varscan2
- PKHD1 | c.9199C>T p.L3067= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV61867289; called by muse, mutect2, varscan2
- PLAAT1 | c.336C>T p.F112= (on ENST00000650797; = p.F7= on NM_020386.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/66 reads (76%) | catalogued as COSV53230880; called by muse, mutect2, varscan2
- POU2F2 | c.1227G>C p.T409= (on ENST00000526816 / NM_001207025.3; = p.T393= on NM_002698.5) | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- PRAG1 | c.2100G>A p.E700= | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, varscan2
- PUS1 | c.684G>C p.T228= | Silent (SNP) | VAF 66/195 reads (34%) | catalogued as COSV59036607; called by muse, mutect2, varscan2
- PWWP2A | c.693C>G p.V231= | Silent (SNP) | VAF 73/255 reads (29%) | called by muse, mutect2, varscan2
- PXDN | c.2367G>C p.G789= | Silent (SNP) | VAF 109/618 reads (18%) | catalogued as COSV53231590; called by muse, mutect2, varscan2
- RBM45 | c.1026A>G p.A342= (on ENST00000616198 / NM_001365579.1; = p.A340= on NM_152945.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- RELN | c.7434G>A p.G2478= | Silent (SNP) | VAF 96/409 reads (23%) | called by muse, mutect2, varscan2
- RELN | c.4650C>T p.D1550= | Silent (SNP) | VAF 84/639 reads (13%) | catalogued as rs1361218663; called by muse, mutect2, varscan2
- RGL3 | c.219C>T p.R73= | Silent (SNP) | VAF 56/97 reads (58%) | catalogued as rs1163166146; called by muse, mutect2, varscan2
- RIF1 | c.2820C>T p.A940= | Silent (SNP) | VAF 27/118 reads (23%) | called by muse, varscan2
- RTL6 | c.393G>A p.P131= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as rs776555729; called by muse, mutect2, varscan2
- RTN1 | c.1113C>T p.A371= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs769910287; called by muse, mutect2, varscan2
- SEMA3F | c.981G>A p.P327= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as rs772034460, COSV50035871; called by muse, mutect2, varscan2
- SHH | c.1101C>T p.I367= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs758397120; called by muse, mutect2, varscan2
- SLC22A6 | c.960C>A p.G320= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- SLC22A6 | c.468A>C p.A156= | Silent (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- SLC6A17 | c.1536C>G p.V512= | Silent (SNP) | VAF 42/163 reads (26%) | called by muse, mutect2, varscan2
- SLC9A1 | c.1209G>T p.V403= | Silent (SNP) | VAF 106/342 reads (31%) | called by muse, mutect2, varscan2
- SOGA1 | c.2895G>A p.T965= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as rs372885110, COSV52927877; called by muse, mutect2
- SP140L | c.906A>G p.L302= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs1390954694; called by muse, mutect2, varscan2
- SPAM1 | c.219C>T p.F73= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV56148862; called by muse, mutect2, varscan2
- SPOCK3 | c.1050A>C p.T350= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV62717493; called by muse, mutect2, varscan2
- SPTLC3 | c.1029C>A p.A343= | Silent (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.861C>A p.L287= | Silent (SNP) | VAF 96/295 reads (33%) | catalogued as COSV66465608, COSV66466319; called by muse, mutect2, varscan2
- STYXL2 | c.348G>C p.L116= | Silent (SNP) | VAF 57/367 reads (16%) | catalogued as COSV54804947, COSV54806994; called by muse, mutect2, varscan2
- SYNPO2 | c.2253C>G p.A751= | Silent (SNP) | VAF 85/253 reads (34%) | called by muse, mutect2, varscan2
- TGFBI | c.534G>A p.R178= | Silent (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- TINAG | c.516A>T p.T172= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52507964; called by muse, varscan2
- TMEM132C | c.1551G>A p.L517= | Silent (SNP) | VAF 60/261 reads (23%) | called by muse, mutect2, varscan2
- TMEM229A | c.408G>T p.A136= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs747377097; called by muse, mutect2, varscan2
- TMPRSS7 | c.168C>A p.G56= | Silent (SNP) | VAF 140/333 reads (42%) | catalogued as rs1462824732; called by muse, mutect2, varscan2
- TNIP2 | c.414C>T p.A138= | Silent (SNP) | VAF 57/373 reads (15%) | catalogued as rs760224582; called by muse, mutect2, varscan2
- TNXB | c.11580C>A p.G3860= (on ENST00000647633; = p.G3613= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 193/1625 reads (12%) | catalogued as rs1326501846; called by muse, mutect2, varscan2
- TNXB | c.1110G>A p.T370= | Silent (SNP) | VAF 25/118 reads (21%) | called by muse, mutect2, varscan2
- TTC21A | c.2205C>T p.G735= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs187725777, COSV57185594; called by muse, mutect2, varscan2
- TTK | c.1578C>A p.S526= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.1284T>A p.T428= | Silent (SNP) | VAF 119/458 reads (26%) | called by muse, mutect2, varscan2
- UHRF1 | c.258G>T p.R86= (on ENST00000612630 / NM_001290050.1; = p.R99= on NM_013282.4) | Silent (SNP) | VAF 236/319 reads (74%) | called by muse, mutect2, varscan2
- VIL1 | c.138C>T p.Y46= | Silent (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- XKR5 | c.42G>T p.A14= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs1014666015; called by muse, mutect2
- ZC3H12C | c.2217A>G p.L739= | Silent (SNP) | VAF 42/281 reads (15%) | catalogued as rs776917208, COSV53712765; called by muse, mutect2, varscan2
- ZMYM2 | c.1926C>T p.C642= | Silent (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- ZNF740 | c.141G>T p.V47= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- AC084082.1 | n.279G>A | RNA (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- AGAP7P | n.1278C>T | RNA (SNP) | VAF 101/1232 reads (8%) | catalogued as rs782278610; called by muse, mutect2
- AK2 | chr1:33008323 C>T | 3'Flank (SNP) | VAF 68/116 reads (59%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821855 G>C | 5'Flank (SNP) | VAF 100/124 reads (81%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502723 G>C | 5'Flank (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- AP003062.1 | n.990T>A | RNA (SNP) | VAF 85/358 reads (24%) | called by muse, varscan2
- AP2A2 | c.*415G>T | 3'UTR (SNP) | VAF 38/150 reads (25%) | called by muse, varscan2
- APOB | c.2436+59C>A | Intron (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- BTNL8 | c.809-53G>A | Intron (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- CD177 | c.-5G>A | 5'UTR (SNP) | VAF 45/238 reads (19%) | catalogued as rs367596455; called by muse, mutect2, varscan2
- CHURC1 | c.328-1294G>T | Intron (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.216C>A | RNA (SNP) | VAF 58/230 reads (25%) | called by muse, mutect2, varscan2
- CRHR2 | chr7:30686562 A>T | 5'Flank (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- DENND6B | c.454-118G>T | Intron (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- ENY2 | c.7-9G>A | Intron (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- EP300 | c.3590+10G>T | Intron (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- FANCD2 | c.*39A>T | 3'UTR (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- GABPA | c.-118C>T | 5'UTR (SNP) | VAF 34/184 reads (18%) | catalogued as rs567696392; called by muse, mutect2, varscan2
- GBE1 | c.143+17791G>C | Intron (SNP) | VAF 16/83 reads (19%) | catalogued as rs76552912, COSV101450065; called by muse, mutect2, varscan2
- GFPT2 | c.7+441C>T | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2
- GLS | c.-2G>T | 5'UTR (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2, varscan2
- HMG20B | c.147+23G>T | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs768220068; called by muse, mutect2, varscan2
- HSPA7 | n.141C>G | RNA (SNP) | VAF 67/677 reads (10%) | called by muse, mutect2, varscan2
- KAT2B | c.*8del | 3'UTR (DEL) | VAF 18/102 reads (18%) | catalogued as rs750062124; called by mutect2, varscan2
- KIAA0100 | c.1015+41G>A | Intron (SNP) | VAF 82/266 reads (31%) | catalogued as rs200725998; called by muse, mutect2, varscan2
- LINC00602 | n.762A>T | RNA (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2, varscan2
- LINC00868 | n.727C>T | RNA (SNP) | VAF 160/254 reads (63%) | catalogued as rs946453592; called by muse, mutect2, varscan2
- LINC01956 | n.263G>C | RNA (SNP) | VAF 76/189 reads (40%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344720 G>T | 5'Flank (SNP) | VAF 123/740 reads (17%) | called by muse, varscan2
- MIP | c.606+29G>A | Intron (SNP) | VAF 53/239 reads (22%) | called by muse, mutect2, varscan2
- MSC | c.-126C>A | 5'UTR (SNP) | VAF 32/218 reads (15%) | called by muse, mutect2, varscan2
- NAA60 | c.*352C>T | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- NEBL | chr10:20899385 A>G | 5'Flank (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- PABPC1L | c.-5_-4delinsT | 5'UTR (DEL) | VAF 50/157 reads (32%) | called by pindel, varscan2*
- PAX9 | c.-126T>A | 5'UTR (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- PENK | c.138+97C>T | Intron (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2
- PNO1 | chr2:68157651 A>G | 5'Flank (SNP) | VAF 57/135 reads (42%) | called by muse, mutect2, varscan2
- PPP3R1 | chr2:68253108 G>A | 5'Flank (SNP) | VAF 34/233 reads (15%) | catalogued as rs1423141565; called by muse, mutect2, varscan2
- PPP4R1L | n.581A>C | RNA (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- PRKN | c.-38C>T | 5'UTR (SNP) | VAF 34/128 reads (27%) | catalogued as rs368314176; called by muse, mutect2, varscan2
- PTHLH | c.-65G>T | 5'UTR (SNP) | VAF 117/270 reads (43%) | called by muse, mutect2, varscan2
- PTN | c.452-8163G>T | Intron (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- RASGRF1 | c.3542+1606G>T | Intron (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100293851; called by muse, mutect2, varscan2
- RBMY2FP | n.390G>C | RNA (SNP) | VAF 125/327 reads (38%) | called by muse, mutect2, varscan2
- RNASET2 | c.446+246T>A | Intron (SNP) | VAF 94/264 reads (36%) | called by muse, mutect2, varscan2
- RNU1-6P | chr1:16535830 G>C | 5'Flank (SNP) | VAF 102/1221 reads (8%) | called by muse, mutect2
- SET | c.113-1612C>A | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as rs780176987; called by muse, mutect2, varscan2
- SLC6A2 | chr16:55705265 C>A | 3'Flank (SNP) | VAF 63/85 reads (74%) | catalogued as rs747735255; called by muse, mutect2, varscan2
- SNORD116-26 | n.70C>A | RNA (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- SNX6 | c.90+329G>C | Intron (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.878C>A | RNA (SNP) | VAF 157/448 reads (35%) | catalogued as rs373582239; called by muse, mutect2, varscan2
- SRP19 | c.-4G>A | 5'UTR (SNP) | VAF 56/200 reads (28%) | called by muse, mutect2, varscan2
- ST13P4 | n.280G>T | RNA (SNP) | VAF 132/530 reads (25%) | called by muse, mutect2, varscan2
- SYT14 | c.*357G>T | 3'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- TAF9 | chr5:69369714 G>C | 5'Flank (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- TANGO2 | c.380+19dup | Intron (INS) | VAF 23/102 reads (23%) | catalogued as rs748385458; called by mutect2, pindel, varscan2
- TFCP2 | c.123-6311G>T | Intron (SNP) | VAF 144/503 reads (29%) | called by muse, mutect2, varscan2
- TMA7 | c.*13G>A | 3'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- TMEM25 | c.805+14A>C | Intron (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- TRIM5 | c.895+68A>C | Intron (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- TRPA1 | c.3150-40G>T | Intron (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10361-5213del | Intron (DEL) | VAF 10/78 reads (13%) | catalogued as COSV100598441; called by mutect2, varscan2
- Unknown | chr11:119498592 C>A | IGR (SNP) | VAF 100/277 reads (36%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866677 G>T | 5'Flank (SNP) | VAF 24/352 reads (7%) | called by muse, mutect2
